Surgical pathology report (de-identified scan), TCGA case TCGA-V4-A9F3, project TCGA-UVM (Uveal Melanoma), tissue source site Institut Curie, specimen TCGA-V4-A9F3-01A (Primary Tumor).

ICD-O-3

Melanoma, epithelioid cell

8721/3

Site Choroid C69.3

Uveal tract C69.4

9/2/16/14

Enucleation of the left eye.

Macroscopy:

The eyeball measures 25 mm in diameter and the posterior optic nerve segment 7 mm, associated with a fragment of adipose tissue of 8 mm. At the section, a pigmented endo-ocular tumor measuring 17X15 mm main lines is observed. Tumor specimens have been taken for cryopreservation and genetic studies, then the piece has been fixed and included entirely according to 12 tissue blocs.

Microscopy

The tumor observed macroscopically presents the histological features of an uveal melanoma. It is composed of large sheets of epithelioid cells, presenting a an abundant cytoplasm and a large nucleus with prominent nucleolus. Presence of mitotic features (5 mitoses per 10 HPF). There amount of pigment is variable according to the areas. The tumor size is 17 mm main line. It is located on the lateral part of the eyeball, arriving close to the ciliary body with focal extension to the ciliary muscle. It remains at a distance from the intra-ocular emergence of the optic nerve. There is a focal tumor extension into the 1/3 inner part of the sclera, without extrascleral extension. At the posterior part of the eyeball, the lamina cribrosa, the optic nerve on its entire course and the meningeal sheaths are free of tumor. The cut end of the optic nerve is also free of tumor.

Conclusion:

Uveal melanoma composed of epithelioid cells.

Tumor size: 17 mm.

Focal extension of the ciliary body.

Tumor infiltration of the 1/3 inner part of the sclera without extrascleral extension.

Optic nerve in its entire course and cut end, and meningeal sheaths free of tumor.

Source: NCI Genomic Data Commons file 0e055d27-697b-4dba-8c51-83325467fedf (TCGA-V4-A9F3.B9FDCA7F-FA12-4FAB-B0B2-92FA9125E6FE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).